TCGA case TCGA-36-2538 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ea880f4-7a78-4cb7-bfe4-54b3c30a812e

Demographics
Sex at birth: female; Age at index: 37 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 37.5 years (13,681 days); Year of diagnosis: 2008; Method of diagnosis: Cytology; FIGO stage: Stage IIIB; Tumor grade: G3; Prior treatment: No; Residual disease: R1; Days to last follow up: 763 days (2.1 years).
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 11-20 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 212 days; Number of cycles: 6; Treatment dose: 4,140 mg; Prescribed dose: 690; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 212 days; Number of cycles: 6; Treatment dose: 1,620 mg; Prescribed dose: 270; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 542 days (1.5 years); Days to treatment end: 682 days (1.9 years); Number of cycles: 6; Treatment dose: 4,080 mg; Prescribed dose: 680; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 542 days (1.5 years); Days to treatment end: 682 days (1.9 years); Number of cycles: 6; Treatment dose: 238 mg; Prescribed dose: 38; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 38.9 years (14,204 days); Days to diagnosis: 523 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 523 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 523 days (1.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 763 days (2.1 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-2538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-36-2538-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25.
  Slide TCGA-36-2538-01A-01-TS1: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 20.
- Sample TCGA-36-2538-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Pacitaxel.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Liposomal Doxorubicin.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-36-2538-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.
- Prior malignancy: Prior malignancy of ovarian cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 763 days; disease-specific survival: no event (censored), 763 days; disease-free interval: event (new tumor event after initially disease-free), 523 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 523 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-36-2538-01A-01D-1043-01): tumor purity 0.71, ploidy 1.75, whole-genome doublings 0.
